Gene-level copy-number profile of tumor specimen TCGA-EE-A2GR-06A from TCGA case TCGA-EE-A2GR, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 79.2 years (28,910 days).
Specimen TCGA-EE-A2GR-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.e865beea-9098-44f5-9247-547ba6a9e97f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EE-A2GR-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1293d56d-8b94-4689-b8f3-c649a5dd6c52

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 41; copy number 1: 19; copy number 2: 3,926; copy number 3: 16,921; copy number 4: 35,852; copy number 5: 1,843; copy number 6: 996; copy number 7: 66; copy number 8: 34; copy number 9: 18; copy number 11: 5; copy number 12: 36; copy number 23: 16; copy number 26: 1; copy number 40: 38.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EE-A2GR-06A-11D-A191-01): tumor purity 0.98, ploidy 3.72, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 41 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:12,685,439–14,069,417, 19 genes: TYRP1, LURAP1L-AS1, RN7SL849P, LURAP1L, Y_RNA, AL161449.2, PRDX1P1, AL161449.1, MPDZ, AL162386.2, AL162386.1, AL583785.1, LINC01235, AL158157.1, LINC00583, PES1P2, AL360089.1, RPL3P11, ATP5PDP3.
- chr9:21,453,802–21,559,900, 1 gene (within-gene range 0–2): MIR31HG.
- chr9:21,480,839–22,214,672, 21 genes: IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 114 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:117,364,899–121,580,524, 95 genes, copy number 11–40 (broad region; genes not listed).
- chr1:149,111,304–149,747,818, 18 genes, copy number 9: AC239804.2, RNVU1-24, AC245297.3, AC245297.1, AC245297.2, 7SK, SEC22B2P, NOTCH2NLC, AC242842.3, NBPF19, PPIAL4C, LINC00869, AC242842.2, AC242842.1, RNVU1-30, FAM91A2P, AC243772.3, RNU1-68P.
- chr12:37,575,587–37,576,384, 1 gene, copy number 26: ZNF970P.

Autosomal genes at a single copy (total copy number 1): 19. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
